Somatic mutation profile of tumor specimen TCGA-V4-A9EX-01A (aliquot TCGA-V4-A9EX-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EX, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.0 years (20,447 days).
Specimen TCGA-V4-A9EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2be4e785-1d9b-4063-a316-9399557b8a5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EX-10A (Blood Derived Normal), aliquot TCGA-V4-A9EX-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24f438b9-85c1-4faa-b345-6884e0c50601

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 101/125 reads (81%) | catalogued as rs1553646284, COSV56230759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 39/81 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CRYBG2 | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as rs1324289433, COSV57488999; called by muse, mutect2, varscan2
- ARFGEF3 | c.2782C>G p.L928V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATG9A | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.147); called by mutect2, varscan2
- DMXL2 | c.4202dup p.S1402Kfs*21 | Frame Shift Ins (INS) | VAF 69/196 reads (35%) | called by mutect2, pindel, varscan2
- GLIS3 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PTPN23 | c.4380T>C p.H1460= | Silent (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- RESF1 | c.3759C>T p.D1253= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs150095870; called by muse, mutect2, varscan2
- SLC18B1 | c.564G>A p.L188= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1227055671; called by muse, mutect2, varscan2
- TNFRSF1A | c.903C>T p.P301= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1338450773; called by muse, varscan2
